CPTAC case C3L-00165 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f5318241-1d15-41d9-be42-0c44558aa96b

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Year of birth: 1969; Vital status: Alive; Country of birth: Mexico.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 47.6 years (17,397 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G4; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 678 days (1.9 years); Progression or recurrence: yes; Days to last follow up: 678 days (1.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 8 cm (a second GDC size field records 6 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 36; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (3 entries)
- Days to follow up: 304 days; Disease response: With Tumor.
- Days to follow up: 678 days (1.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 304 days; Karnofsky performance status: 50.
- Days to follow up: 678 days (1.9 years); Disease response: With Tumor; Karnofsky performance status: 50.

Other clinical attributes
- Weight: 60.78 kg; Height: 167.64 cm; BMI: 21.63.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00165-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 774 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00165-25: Section location: Lower pole; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3L-00165-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 212 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00165-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
